Surgical pathology report (de-identified scan), TCGA case TCGA-74-6581, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Swedish Neurosciences, specimen TCGA-74-6581-01A (Primary Tumor).

[page 1 of 3]
Encounter Date: [REDACTED]

Results: PATHOLOGY / NON GYN
CYTOLOGY [REDACTED]

Status: [REDACTED]

TCGA-74-6581

Collection Information

Collection Date [REDACTED]

Collection Time: [REDACTED]

Lab Information

Lab [REDACTED]

Component Results

**SURGICAL PATHOLOGY
REPORT**

Case Number: [REDACTED]

Procedures/Addenda Present

Collected: [REDACTED]

Received: [REDACTED]

Signed Out: [REDACTED]

Reported: [REDACTED]

CLINICAL INFORMATION:

Clinical history: Not provided.

INTRAPROCEDURAL CONSULTATION:

A. Right temporal mass (frozen section and crush prep): Extensively necrotic hypercellular atypical glial proliferation, compatible with high-grade glial neoplasm, favor glioblastoma multiforme.

GROSS DESCRIPTION:

A. Received fresh, labeled [REDACTED] and designated "right temporal mass", is a 2.0 x 1.5 x 0.5 cm fragment of necrotic, tan, cerebral soft tissue. A crush prep was previously performed. The specimen was previously frozen and is entirely submitted in AFS.

B. Received in formalin, labeled [REDACTED] and designated "right temporal mass", is a 2.7 x 2.5 x 0.7 cm aggregate of multiple fragments of pink-white cerebral soft tissue. The specimen is entirely submitted in cassette B.

C. Received in formalin, labeled [REDACTED] and designated "CUSA contents", is a 5.0 x 3.0 x 1.5 cm aggregate of multiple fragments of necrotic tan soft tissue, which are entirely submitted in C1-C2.

FINAL PATHOLOGIC DIAGNOSIS:

A. BRAIN, RIGHT TEMPORAL MASS, BIOPSY:

B. BRAIN, RIGHT TEMPORAL MASS, RESECTION:

C. CUSA CONTENTS:

Glioblastoma, with small cell features, WHO grade IV/IV, with the following features:

- Degree of cellularity: high.
- Microvascular proliferation: present.
- Necrosis: present with pseudopalisading.
- Mitotic rate: 18 per 10 HPFs.
- Other features: FISH, p53 and MGMT studies (PCR and Immunohistochemistry) for part B: pending.

Electronically Signed By

PROCEDURES/ADDENDA:

[page 2 of 3]
Encounter Date: [REDACTED]

ICC- IMMUNOHISTOCHEMISTRY Date Ordered: [REDACTED] Status: [REDACTED]

Date Complete: [REDACTED]

By: [REDACTED]

Date Reported: [REDACTED]

Interpretation
{Not Entered}

Results-Comments

B. RIGHT TEMPORAL MASS, IMMUNOHISTOCHEMISTRY RESULT:
-p53 IMMUNOSTAIN IS POSITIVE IN TUMOR, CONSISTENT WITH
GLIOBLASTOMA.

FISH Date Ordered: [REDACTED] Status: [REDACTED]

Date Complete: [REDACTED]

By: [REDACTED]

Date Reported: [REDACTED]

Interpretation

B. Right temporal brain, FISH results:
-Negative for a 1p/19q codeletion.
-Positive for polysomy 1 and 19.
-Positive for amplification of EGFR.
-Positive for monosomy 10/PTEN.

Results-Comments

At the request of [REDACTED] representative sections of the tumor (Block B1)
were submitted for FISH analysis. Results are consistent with the stated
diagnosis. Please see separate report by [REDACTED]

ICC- IMMUNOHISTOCHEMISTRY Date Ordered: [REDACTED] Status: [REDACTED]

Date Complete: [REDACTED]

By: [REDACTED]

Date Reported: [REDACTED]

Interpretation

Brain, right temporal mass, immunohistochemistry results:

-Tumor is positive for MGMT by immunohistochemistry (approximately 25%
positive).

Results-Comments

At the request of [REDACTED] representative sections of the tumor (block B1)
were submitted to immunohistochemistry to MGMT. The result is approximately
25% of the tumor positive. Endothelial cells are positive internal controls.

[page 3 of 3]
Encounter Date: [REDACTED]

MGMT by PCR Date Ordered: [REDACTED]

Status: [REDACTED]

Date Complete: [REDACTED]

By: [REDACTED]

Date Reported: [REDACTED]

Interpretation
{Not Entered}

Results-Comments

B. RIGHT TEMPORAL MASS, MGMT Methylation Assay, Result:
-Gene Methylation NOT detected.

Please see full report from [REDACTED] for additional details accession
[REDACTED]

[Lab Inquiry](#)

[View Complete Results](#)

[Reviewed by List](#)

Order Details

[Order Details](#)

[REDACTED]	Dept Phone: [REDACTED]	Description: [REDACTED]
[REDACTED] Hospital	Encounter # [REDACTED]	Department: [REDACTED]
Encounter		
MRN: [REDACTED]		

Order

PATHOLOGY / NON GYN CYTOLOGY [REDACTED]

Patient Information	Patient Name	Sex	DOB
---------------------	--------------	-----	-----

[REDACTED]	[REDACTED]		
------------	------------	--	--

Admitted	Date	CSN
----------	------	-----

[REDACTED]	[REDACTED]	[REDACTED]
------------	------------	------------

Source: NCI Genomic Data Commons file 1fc62a94-179a-4008-a1ca-c1ab88b2d3c7 (TCGA-74-6581.7AB73575-CD7D-434F-B21D-FCFFB52C3A4D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).